Somatic mutation profile of tumor specimen TCGA-YU-A90Q-01A (aliquot TCGA-YU-A90Q-01A-11D-A435-10) from TCGA case TCGA-YU-A90Q, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 21.5 years (7,846 days).
Specimen TCGA-YU-A90Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 646e63aa-8e4f-4876-8814-1750a86092a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YU-A90Q-10A (Blood Derived Normal), aliquot TCGA-YU-A90Q-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2620739f-0f58-4904-9ec7-c6d48464efc9

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Splice Site 1, 3'Flank 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 27/77 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 28/182 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC158 | c.1150-1G>A p.X384_splice | Splice Site (SNP) | VAF 15/74 reads (20%) | catalogued as COSV66355091; called by muse, mutect2, varscan2
- AAAS | c.936_937del p.V313Lfs*9 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by pindel, varscan2
- POM121 | chr7:72948362 G>A | 3'Flank (SNP) | VAF 7/58 reads (12%) | catalogued as rs201837093; called by muse, mutect2, varscan2
- TUBB8P7 | n.1909G>A | RNA (SNP) | VAF 13/40 reads (33%) | catalogued as rs747600131; called by muse, mutect2
